Somatic mutation profile of tumor specimen C3L-06333-01 (aliquot CPT0362100009) from CPTAC case C3L-06333, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 81.4 years (29,744 days).
Specimen C3L-06333-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c2b08f6-4728-42f0-a410-4e674120bbb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06333-31 (Blood Derived Normal), aliquot CPT0362160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df89494a-6ee4-449c-8a22-f61dd20e2249

The open-access MAF lists 568 somatic variants for this specimen: 381 protein-altering or splice-affecting, 172 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 349, Silent 172, Nonsense Mutation 18, Intron 10, Splice Region 9, 3'UTR 4, Splice Site 2, Translation Start Site 1, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.8542C>T p.L2848F | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs936195456; called by muse, mutect2, varscan2
- ACACB | c.3823G>A p.D1275N | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361682154, COSV100622930; called by muse, mutect2, varscan2
- ACVRL1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 126/544 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs199652672; called by muse, mutect2, varscan2
- ADAM2 | c.345G>A p.R115= | Splice Region (SNP) | VAF 62/180 reads (34%) | catalogued as COSV55868462; called by muse, mutect2, varscan2
- ADGRV1 | c.12590C>T p.S4197F | Missense Mutation (SNP) | VAF 104/409 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.036); catalogued as rs868482557, COSV67995255; called by muse, mutect2, varscan2
- ADORA3 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 121/397 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.033); catalogued as COSV53985074; called by muse, mutect2, varscan2
- AGO4 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV64616595; called by muse, mutect2
- ANKRD30B | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 120/355 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV62821975, COSV99080928; called by muse, mutect2, varscan2
- APBA1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 134/309 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs759515322, COSV55231757, COSV55231856; called by muse, mutect2, varscan2
- ARHGAP18 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs191935343, COSV63765320; called by muse, mutect2, varscan2
- ASTN1 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.801); catalogued as rs1356115368, COSV56069844; called by muse, mutect2, varscan2
- ATP11B | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60030349; called by muse, mutect2, varscan2
- BRWD3 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs1165613538, COSV64749907; called by muse, mutect2, varscan2
- C7 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as COSV57482318; called by muse, mutect2, varscan2
- CACNG2 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 75/483 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1004539198; called by muse, mutect2, varscan2
- CALY | c.360G>A p.R120= | Splice Region (SNP) | VAF 39/210 reads (19%) | catalogued as COSV53309961; called by muse, mutect2, varscan2
- CAMK1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 54/431 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs755234937; called by muse, mutect2, varscan2
- CASR | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 139/426 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1230573005; called by muse, mutect2, varscan2
- CCER1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 163/416 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs748776182, COSV62648591; called by muse, mutect2, varscan2
- CENPU | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs748968537; called by muse, mutect2, varscan2
- CFAP74 | c.675G>A p.R225= | Splice Region (SNP) | VAF 76/223 reads (34%) | catalogued as COSV54568293; called by muse, mutect2, varscan2
- CGAS | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.033); catalogued as COSV64808542; called by muse, mutect2, varscan2
- CLDN16 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53228447; called by muse, mutect2, varscan2
- CLIP1 | c.1426C>T p.R476C (on ENST00000620786 / NM_001247997.1; = p.R465C on NM_002956.2) | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs149025674; called by muse, mutect2, varscan2
- CLK2 | c.847G>A p.D283N (on ENST00000368361 / NM_001294339.2; = p.D282N on NM_003993.4) | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV100226853, COSV56944706; called by muse, mutect2, varscan2
- COL22A1 | c.2399A>C p.K800T | Missense Mutation (SNP) | VAF 51/528 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs780196638; called by muse, mutect2
- COL6A5 | c.4950G>A p.Q1650= | Splice Region (SNP) | VAF 54/374 reads (14%) | catalogued as rs1415935017; called by muse, mutect2, varscan2
- COL7A1 | c.4744C>T p.P1582S | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs146418495; called by muse, mutect2, varscan2
- CPNE7 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1440143154; called by muse, mutect2, varscan2
- CSMD3 | c.4616G>A p.R1539Q (on ENST00000297405 / NM_001363185.1; = p.R1435Q on NM_052900.3) | Missense Mutation (SNP) | VAF 101/424 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1472368863, COSV52210021; called by muse, mutect2, varscan2
- CTAGE1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs377367059; called by muse, mutect2, varscan2
- CTNND2 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 106/396 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV58884827; called by muse, mutect2, varscan2
- CYLC2 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as COSV100872636, COSV66338137; called by muse, mutect2, varscan2
- CYP4A22 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 119/390 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs769147059; called by muse, mutect2, varscan2
- CYP4Z1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61965208; called by muse, mutect2, varscan2
- DCDC2 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 113/320 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65832442; called by muse, mutect2, varscan2
- DHRS9 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs200917304; called by muse, mutect2, varscan2
- DISP3 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53832211; called by muse, mutect2, varscan2
- DMD | c.6596T>G p.L2199R | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV58938090; called by muse, mutect2, varscan2
- DNAH5 | c.12631G>A p.E4211K | Missense Mutation (SNP) | VAF 60/459 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762673561, COSV54204698, COSV54216995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.3500C>T p.S1167F | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99444954; called by muse, mutect2, varscan2
- DSCAML1 | c.2252G>A p.R751Q (on ENST00000321322; = p.R691Q on NM_020693.4) | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); catalogued as rs768520860, COSV100355591, COSV100357197; called by muse, mutect2, varscan2
- DSE | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs199585272; called by muse, mutect2, varscan2
- DTX1 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.194); catalogued as rs1293503052; called by muse, mutect2, varscan2
- DYNC1I1 | c.426-1G>A p.X142_splice | Splice Site (SNP) | VAF 41/234 reads (18%) | catalogued as COSV99070527; called by muse, mutect2, varscan2
- EGFLAM | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 57/410 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1209764585; called by muse, mutect2, varscan2
- EPB41 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs561329874, COSV58049880; called by muse, mutect2, varscan2
- EPB41L4A | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 85/326 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1389356816, COSV54880511; called by muse, mutect2, varscan2
- F8 | c.4633C>T p.L1545F | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.641); catalogued as rs1201626219; called by muse, varscan2
- FAM102B | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs975968467; called by muse, varscan2
- FBN2 | c.3710G>A p.R1237H | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs142185964, COSV52513207; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FBXO16 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 88/377 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.317); catalogued as COSV60777312; called by muse, mutect2, varscan2
- FLNC | c.6560G>A p.R2187H | Missense Mutation (SNP) | VAF 65/432 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.7); catalogued as COSV57956161; called by muse, mutect2, varscan2
- FLRT1 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 78/726 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.154); catalogued as rs1312216516; called by muse, mutect2, varscan2
- FMN2 | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as rs752237802, COSV60416576; called by muse, varscan2
- FOXD4L5 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 81/1113 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.199); catalogued as rs1190776212; called by muse, mutect2
- FREM1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1169108690; called by muse, mutect2, varscan2
- FXYD1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs755353547, COSV99544942; called by muse, mutect2
- G6PC | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs767487454; called by muse, mutect2, varscan2
- GCNT1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs759026554; called by muse, mutect2, varscan2
- GIMAP1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 55/380 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100211996, COSV56189241; called by muse, mutect2, varscan2
- GLIPR1L2 | c.670+5G>A | Splice Region (SNP) | VAF 46/374 reads (12%) | catalogued as rs1262972544; called by muse, mutect2, varscan2
- H1-4 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 67/520 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs149077445; called by muse, mutect2, varscan2
- HDAC7 | c.337C>T p.P113S (on ENST00000427332; = p.P152S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs936509800; called by muse, mutect2, varscan2
- HEPH | c.2423G>A p.G808E (on ENST00000343002; = p.G541E on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.241); catalogued as rs1296996474; called by muse, mutect2
- HHLA2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 127/468 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100755519; called by muse, mutect2, varscan2
- HID1 | c.1797G>A p.M599I | Missense Mutation (SNP) | VAF 62/500 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs750806193; called by muse, mutect2, varscan2
- HOMER2 | c.631T>C p.W211R (on ENST00000304231 / NM_199330.3; = p.W200R on NM_004839.4) | Missense Mutation (SNP) | VAF 142/385 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs765272397; called by muse, mutect2, varscan2
- HTR1B | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 187/385 reads (49%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs755489481; called by muse, mutect2, varscan2
- IFIH1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs759212820, COSV55125721; called by muse, mutect2, varscan2
- IL22RA1 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 117/430 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1193501072; called by muse, mutect2, varscan2
- INPPL1 | c.3365C>T p.S1122L | Missense Mutation (SNP) | VAF 93/676 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs147991973; called by muse, mutect2, varscan2
- IQCN | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 134/441 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755534780, COSV66572599; called by muse, mutect2, varscan2
- ITIH6 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 68/382 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1409670656; called by muse, mutect2, varscan2
- JPH2 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 70/565 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as rs774829958; called by muse, varscan2
- KAT14 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 126/469 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV66608340; called by muse, mutect2, varscan2
- KCNA2 | c.311T>A p.V104E | Missense Mutation (SNP) | VAF 61/408 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60371241; called by muse, mutect2, varscan2
- KCNJ12 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 134/637 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59176557; called by muse, mutect2, varscan2
- KCNMB4 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867000688, COSV50690718; called by muse, mutect2, varscan2
- KIAA1217 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs887457879, COSV64601559; called by muse, mutect2, varscan2
- KIAA1328 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99694388; called by muse, mutect2, varscan2
- KRT13 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs1165181435, COSV99877439; called by muse, mutect2, varscan2
- KRT78 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs775478505; called by muse, mutect2, varscan2
- LIN54 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); catalogued as COSV61200550; called by muse, mutect2, varscan2
- LMBRD1 | c.1673C>T p.S558F (on ENST00000649011; = p.S536F on NM_018368.4) | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs1369030632; called by muse, mutect2, varscan2
- LRRIQ1 | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV67824944, COSV67837743; called by muse, mutect2, varscan2
- M1AP | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.68); catalogued as COSV99304179; called by muse, varscan2
- MAGEB6 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 124/409 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV66872068, COSV66872965; called by muse, mutect2, varscan2
- MAGEC1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.831); catalogued as COSV53571962; called by muse, mutect2, varscan2
- MAGI1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 98/552 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1215511516; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3862G>A p.G1288R | Missense Mutation (SNP) | VAF 60/447 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99169396; called by muse, mutect2, varscan2
- MED12L | c.4610C>A p.T1537N | Missense Mutation (SNP) | VAF 101/344 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs1367538051; called by muse, mutect2, varscan2
- MEGF10 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 74/259 reads (29%) | catalogued as rs1279221790, COSV57245287; called by muse, mutect2, varscan2
- MEIS3 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs779646781, COSV58983273; called by muse, mutect2, varscan2
- MRC2 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 107/428 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.167); catalogued as rs757068232, COSV57643780; called by muse, varscan2
- MTUS2 | c.2719G>A p.G907S | Missense Mutation (SNP) | VAF 171/458 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771360886, COSV54993678; called by muse, mutect2, varscan2
- MUC4 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 181/641 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.65); catalogued as rs767195725; called by muse, mutect2, varscan2
- MYO15B | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 50/411 reads (12%) | SIFT tolerated, low confidence (0.06); catalogued as rs1172979002; called by muse, mutect2, varscan2
- NLRP11 | c.1775G>A p.R592K | Missense Mutation (SNP) | VAF 43/395 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1374818421; called by muse, mutect2, varscan2
- NLRP5 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV66767191; called by muse, mutect2, varscan2
- NLRP9 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 88/346 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV60463477; called by muse, mutect2, varscan2
- NPAP1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.198); catalogued as rs746599372, COSV61504828, COSV61508788; called by muse, mutect2, varscan2
- NPAS4 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 62/460 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs777170239, COSV60650041; called by muse, mutect2, varscan2
- NPY1R | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.659); catalogued as COSV99648660; called by muse, mutect2, varscan2
- NXPH4 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 67/510 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs748690073; called by muse, mutect2, varscan2
- OGFR | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 162/516 reads (31%) | catalogued as rs373481743, COSV51700968; called by muse, varscan2
- OR13C4 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV52926173, COSV99470316; called by muse, mutect2, varscan2
- OR2B2 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 151/344 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV57579851; called by muse, mutect2, varscan2
- OR3A3 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 72/356 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52168463; called by muse, mutect2, varscan2
- OR6A2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs763926030; called by muse, mutect2, varscan2
- OR6F1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57466947; called by muse, mutect2, varscan2
- PCDHA2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 122/536 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); catalogued as rs782027744, COSV65366259; called by muse, mutect2, varscan2
- PCDHA5 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 86/352 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.102); catalogued as COSV65355925; called by muse, mutect2, varscan2
- PCDHB11 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV61310480, COSV61312804; called by muse, mutect2, varscan2
- PCDHGB7 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 59/447 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs768683069; called by muse, mutect2, varscan2
- PCLO | c.7894C>T p.P2632S | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs866817112, COSV61620909; called by muse, mutect2, varscan2
- PEG3 | c.2992G>A p.G998R | Missense Mutation (SNP) | VAF 113/414 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1355171473; called by muse, mutect2, varscan2
- PLCH2 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV53950012; called by muse, mutect2, varscan2
- POTEE | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as rs1282119649; called by muse, mutect2
- PSG8 | c.974C>T p.T325I | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs376880595; called by muse, mutect2, varscan2
- RAD51AP2 | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV67587634; called by muse, mutect2, varscan2
- RELN | c.4945C>T p.R1649C | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368740749; called by muse, mutect2, varscan2
- RGN | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 63/400 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs781873133; called by muse, mutect2, varscan2
- RGS9 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 88/346 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV52222656; called by muse, mutect2, varscan2
- RNF31 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53758426; called by muse, mutect2, varscan2
- ROR2 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 169/411 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV65219300; called by muse, mutect2, varscan2
- RYR2 | c.3608C>T p.P1203L | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV63663418; called by muse, mutect2, varscan2
- RYR3 | c.10450C>T p.R3484W (on ENST00000389232; = p.R3485W on NM_001036.6) | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285679898; called by muse, mutect2, varscan2
- SCAPER | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 46/404 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57755677; called by muse, mutect2, varscan2
- SCN10A | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs772436481; called by muse, mutect2, varscan2
- SDK1 | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 49/420 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67360882; called by muse, mutect2, varscan2
- SELP | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55250278; called by muse, mutect2, varscan2
- SH3TC1 | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 115/467 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as rs1561708141; called by muse, mutect2, varscan2
- SIRPB2 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.636); catalogued as COSV63123392; called by muse, mutect2, varscan2
- SLC15A3 | c.1067A>G p.N356S | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99136122; called by muse, mutect2, varscan2
- SLC26A5 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100099921; called by muse, mutect2, varscan2
- SLC44A5 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV63765317; called by muse, mutect2, varscan2
- SLC6A12 | c.579G>A p.E193= | Splice Region (SNP) | VAF 31/401 reads (8%) | catalogued as rs1479991572; called by muse, mutect2
- SLC9C1 | c.2701G>A p.G901S | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV59892204; called by muse, mutect2, varscan2
- SLCO1B3 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV53933034, COSV53936843; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1925C>T p.S642L (on ENST00000540229 / NM_001371097.1; = p.S581L on NM_001009562.4) | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.07); catalogued as rs751847643, COSV67443086; called by muse, mutect2, varscan2
- SLCO6A1 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs1407724157, COSV65806696; called by muse, mutect2, varscan2
- SLIT3 | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as rs767144266; called by muse, mutect2, varscan2
- SMYD1 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV101352421; called by muse, mutect2, varscan2
- SNTG1 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 101/451 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV52462211; called by muse, mutect2, varscan2
- SORCS3 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV63802474, COSV63803359; called by muse, mutect2, varscan2
- SOX8 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 180/724 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1268997374; called by muse, mutect2, varscan2
- SPEG | c.4438G>C p.E1480Q | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.865); catalogued as rs1326153683, COSV56679650; called by muse, mutect2, varscan2
- SPHKAP | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 68/380 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60894304; called by muse, mutect2, varscan2
- ST6GAL2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 98/536 reads (18%) | PolyPhen benign (0); catalogued as COSV64526982; called by muse, mutect2
- STARD9 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99313657; called by muse, mutect2, varscan2
- STK31 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302905060, COSV63458490; called by muse, mutect2, varscan2
- SULF2 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202153241; called by muse, mutect2
- SULT1C3 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61252746; called by muse, mutect2, varscan2
- TAOK1 | c.1564A>G p.M522V | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs140542550; called by muse, mutect2, varscan2
- TECTA | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs956262010, COSV50742116; called by muse, mutect2, varscan2
- TEX13A | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV61171931; called by muse, mutect2, varscan2
- THAP7 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1355360528; called by muse, mutect2, varscan2
- TMEM132B | c.2348G>A p.G783E | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54754134; called by muse, mutect2, varscan2
- TMEM132D | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 99/401 reads (25%) | catalogued as COSV67158768; called by muse, mutect2, varscan2
- TMEM212 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs534712067, COSV58002387; called by muse, mutect2, varscan2
- TMEM63C | c.581_583del p.F194del | In Frame Del (DEL) | VAF 30/220 reads (14%) | catalogued as rs1566628065; called by pindel, varscan2
- TNFRSF13B | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 63/451 reads (14%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as rs747078163, COSV55430548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC12 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs1184411950, COSV59099596; called by muse, mutect2, varscan2
- TTC34 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 100/581 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1401659710; called by muse, mutect2, varscan2
- TTN | c.77611G>A p.E25871K (on ENST00000591111; = p.E18447K on NM_003319.4) | Missense Mutation (SNP) | VAF 39/337 reads (12%) | PolyPhen benign (0.053); catalogued as COSV60244687; called by muse, mutect2, varscan2
- TTN | c.67363G>A p.D22455N (on ENST00000591111; = p.D15031N on NM_003319.4) | Missense Mutation (SNP) | VAF 52/327 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV60339642; called by muse, mutect2, varscan2
- USP29 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs267605720, COSV54240849, COSV54242182; called by muse, mutect2, varscan2
- VAV1 | c.1026G>A p.E342= | Splice Region (SNP) | VAF 30/344 reads (9%) | catalogued as COSV100409612; called by muse, mutect2
- VEPH1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62880045; called by muse, mutect2, varscan2
- VPS13B | c.9853C>T p.P3285S | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as COSV62134981; called by muse, mutect2, varscan2
- VPS52 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 124/345 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as rs1171726984; called by muse, mutect2, varscan2
- VPS8 | c.1024C>T p.P342S (on ENST00000625842 / NM_001349294.1; = p.P340S on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.84); catalogued as rs1327883411; called by muse, mutect2, varscan2
- VTA1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs753392312, COSV62660161; called by muse, mutect2, varscan2
- VWA3A | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV67014045; called by muse, mutect2, varscan2
- WDFY4 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1439790372, COSV100302212, COSV57431000; called by muse, mutect2, varscan2
- WNK2 | c.5741C>T p.S1914L (on ENST00000297954 / NM_001282394.1; = p.S1877L on NM_006648.3) | Missense Mutation (SNP) | VAF 101/321 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs372209963; called by muse, mutect2, varscan2
- ZFHX2 | c.6184G>A p.G2062R | Missense Mutation (SNP) | VAF 143/363 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs951607285; called by muse, mutect2, varscan2
- ZNF141 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs781835417, COSV53662174; called by muse, mutect2, varscan2
- ZNF184 | c.2201C>T p.S734F | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV53005816; called by muse, mutect2, varscan2
- ZNF229 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs756113024, COSV52161987; called by muse, mutect2, varscan2
- ZNF354C | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100203456; called by muse, mutect2, varscan2
- ZNF382 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs367633489; called by muse, mutect2, varscan2
- ZNF578 | c.967T>C p.S323P | Missense Mutation (SNP) | VAF 99/430 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV69736949; called by muse, mutect2, varscan2
- ZNF592 | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 158/412 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758325813, COSV55435440; called by muse, mutect2, varscan2
- ZNF599 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 117/511 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.648); catalogued as rs1345356540, COSV100251093; called by muse, mutect2, varscan2
- ZNF676 | c.1133T>C p.F378S (on ENST00000650058; = p.F346S on NM_001001411.3) | Missense Mutation (SNP) | VAF 72/629 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV68095305; called by muse, mutect2, varscan2
- ZNF677 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV61720866, COSV61721589; called by muse, mutect2, varscan2
- ZNF681 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV68073514; called by muse, mutect2, varscan2
- ADGB | c.4045G>T p.V1349F | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADGRV1 | c.4373C>T p.T1458I | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AEBP2 | c.1463T>A p.L488* | Nonsense Mutation (SNP) | VAF 30/247 reads (12%) | called by muse, mutect2, varscan2
- AGBL4 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGO2 | c.1058T>C p.I353T | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.265); called by muse, mutect2
- ALDH1B1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ANKFN1 | c.132A>T p.L44F | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ANKRD30B | c.3369T>G p.N1123K | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- APLP1 | c.1622T>G p.M541R (on ENST00000221891 / NM_001024807.3; = p.M540R on NM_005166.4) | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAP2 | c.2229T>G p.D743E | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP31 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 48/453 reads (11%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP5 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP6 | c.2337T>A p.N779K (on ENST00000337414 / NM_013427.3; = p.N576K on NM_013423.3) | Missense Mutation (SNP) | VAF 77/516 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ASAP3 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 158/460 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG9A | c.1150G>C p.A384P | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B9D2 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- B9D2 | c.69C>A p.C23* | Nonsense Mutation (SNP) | VAF 78/315 reads (25%) | called by muse, mutect2, varscan2
- BIRC6 | c.11429G>A p.R3810K | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- BRINP1 | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3 | c.72C>T p.P24= | Splice Region (SNP) | VAF 29/283 reads (10%) | called by muse, mutect2, varscan2
- C5AR2 | c.764T>A p.V255E | Missense Mutation (SNP) | VAF 68/548 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CARD6 | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 56/429 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CASQ1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CBLB | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2
- CBY2 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 164/416 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CCDC105 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 54/488 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CCDC154 | c.1921C>T p.L641F | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CDC27 | c.1255A>G p.T419A | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDH24 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 94/288 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDX1 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 51/397 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CGREF1 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CLOCK | c.2243C>A p.S748* | Nonsense Mutation (SNP) | VAF 44/379 reads (12%) | called by muse, mutect2, varscan2
- CMYA5 | c.2224T>C p.F742L | Missense Mutation (SNP) | VAF 122/486 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL22A1 | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 95/688 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL3A1 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREB3L1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 79/527 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CREB5 | c.1478C>T p.T493I (on ENST00000357727 / NM_182898.4; = p.T486I on NM_004904.3) | Missense Mutation (SNP) | VAF 43/367 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CST9L | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CYBB | c.1096T>C p.F366L | Missense Mutation (SNP) | VAF 104/427 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP2D6 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 88/609 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- DBH | c.832C>A p.H278N | Missense Mutation (SNP) | VAF 58/415 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DDX18 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 50/305 reads (16%) | called by muse, mutect2, varscan2
- DES | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DMD | c.10655G>T p.S3552I | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DMD | c.2423T>C p.L808P | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH3 | c.8483G>A p.G2828E | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.8482G>A p.G2828R | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.9073A>G p.T3025A | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJC13 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2
- DPYD | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EPHB2 | c.2257C>T p.L753F (on ENST00000400191 / NM_001309193.2; = p.L754F on NM_004442.7) | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- F8 | c.4744G>A p.D1582N | Missense Mutation (SNP) | VAF 71/334 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, varscan2
- FAM47A | c.840T>A p.C280* | Nonsense Mutation (SNP) | VAF 82/464 reads (18%) | called by muse, mutect2, varscan2
- FLNA | c.4273A>C p.N1425H | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- FLRT1 | c.991T>G p.F331V | Missense Mutation (SNP) | VAF 83/736 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FO393400.1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FOCAD | c.27T>G p.F9L | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FOCAD | c.3262C>T p.H1088Y | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- FZD10 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 87/501 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GDNF | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 58/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GK3P | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 72/456 reads (16%) | called by muse, mutect2, varscan2
- GPC4 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR180 | c.854C>G p.P285R | Missense Mutation (SNP) | VAF 132/343 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- GRB10 | c.1468A>G p.T490A (on ENST00000398812; = p.T444A on NM_001001549.3) | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAPLN3 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 230/596 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- HBD | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- HERC1 | c.8018C>A p.P2673Q | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HHLA2 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 55/447 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- HMGXB4 | c.947T>G p.I316S | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HSCB | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.355); called by muse, mutect2
- IL16 | c.2153C>T p.S718F (on ENST00000302987 / NM_172217.5; = p.S17F on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/424 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL20RA | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IMPG1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KLHDC7B | c.467G>A p.G156E (on ENST00000395676; = p.G797E on NM_138433.5) | Missense Mutation (SNP) | VAF 69/600 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL26 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 66/513 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KYAT3 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LAMA5 | c.5741C>T p.P1914L | Missense Mutation (SNP) | VAF 61/423 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- LAMP1 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCA5 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LEO1 | c.1468A>G p.T490A | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, varscan2
- LGALS3BP | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 93/522 reads (18%) | called by muse, mutect2, varscan2
- LRFN4 | c.1373A>C p.H458P | Missense Mutation (SNP) | VAF 65/439 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- LRG1 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRRC74B | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 79/432 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- LRRIQ3 | c.1802A>G p.Q601R | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- MAGEA6 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MAN2B2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- MAP7D3 | c.1765A>G p.S589G | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MCF2L2 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MED12L | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MGAM2 | c.2957C>T p.S986F | Missense Mutation (SNP) | VAF 103/387 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MIS12 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 48/425 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP19 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 69/456 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MROH5 | c.3665G>A p.W1222* | Nonsense Mutation (SNP) | VAF 41/346 reads (12%) | called by muse, mutect2, varscan2
- MROH5 | c.3109C>T p.P1037S | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.329); called by muse, mutect2
- MRPL21 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MUC16 | c.27502C>T p.H9168Y | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- MUC16 | c.19069G>A p.E6357K | Missense Mutation (SNP) | VAF 81/339 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- MYH6 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MYOCD | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFV3 | c.295C>T p.P99S (on ENST00000340344 / NM_001001503.2; = p.P464S on NM_021075.4) | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEURL1B | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NEXMIF | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 71/353 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- NLN | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NOS1 | c.2884C>T p.L962F | Missense Mutation (SNP) | VAF 51/363 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- NRAP | c.4379T>C p.V1460A (on ENST00000359988 / NM_001322945.2; = p.V1425A on NM_006175.4) | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP98 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- OR2L2 | c.466T>G p.C156G | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- OR52E6 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 82/274 reads (30%) | called by muse, mutect2, varscan2
- OTOG | c.4171G>A p.G1391S | Missense Mutation (SNP) | VAF 124/415 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OXCT1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- OXR1 | c.92G>A p.G31E (on ENST00000442977 / NM_001198532.1; = p.G30E on NM_018002.3) | Missense Mutation (SNP) | VAF 109/449 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAGE1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PCDHGB5 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 63/410 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PEG3 | c.4418A>T p.E1473V | Missense Mutation (SNP) | VAF 60/463 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PHF12 | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHF6 | c.116T>G p.V39G | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PHYHIP | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 169/404 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIGG | c.1334T>C p.V445A (on ENST00000453061 / NM_001127178.3; = p.V437A on NM_017733.4) | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PKHD1L1 | c.6159A>T p.E2053D | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLCH1 | c.586C>T p.Q196* (on ENST00000340059 / NM_001130960.2; = p.Q208* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/307 reads (8%) | called by muse, mutect2
- PMEPA1 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- POTEE | c.3035G>A p.R1012K | Missense Mutation (SNP) | VAF 44/580 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PPDPFL | c.83T>A p.L28* | Nonsense Mutation (SNP) | VAF 39/367 reads (11%) | called by muse, mutect2, varscan2
- PPP4R1 | c.2635C>T p.P879S (on ENST00000400556 / NM_001042388.3; = p.P862S on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PRAMEF18 | c.639G>A p.W213* | Nonsense Mutation (SNP) | VAF 38/715 reads (5%) | called by muse, mutect2
- PSG3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 119/420 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- PSG6 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PTPN3 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 139/426 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- PYGM | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 52/572 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2
- RAG1 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 59/229 reads (26%) | called by muse, mutect2, varscan2
- RCC1L | c.1168T>C p.F390L | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RSPH3 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 127/391 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPH6A | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTN4RL2 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 95/586 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RUFY4 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- SARDH | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SBK3 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 65/507 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SBK3 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 65/510 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SEMA5A | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SEMG1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEPTIN8 | c.839T>C p.L280S | Missense Mutation (SNP) | VAF 113/458 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SGO2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SHANK2 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 90/341 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SLC17A7 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLCO2B1 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 48/410 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SMPD4 | c.1308C>T p.V436= (on ENST00000409031 / NM_017951.4; = p.V407= on NM_017751.4) | Splice Region (SNP) | VAF 59/329 reads (18%) | called by muse, mutect2, varscan2
- SNRPN | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SNTA1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 50/522 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.035); called by muse, mutect2
- SNX20 | c.539T>C p.F180S | Missense Mutation (SNP) | VAF 135/361 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SPATA31D1 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 96/443 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SPIN1 | c.590-1G>C p.X197_splice | Splice Site (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
- SQOR | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SRCIN1 | c.1871G>A p.R624Q (on ENST00000621492; = p.R590Q on NM_025248.3) | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SRPK2 | c.431T>G p.M144R | Missense Mutation (SNP) | VAF 100/356 reads (28%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- STEAP2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- STING1 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 39/391 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUPT6H | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- SVOP | c.912A>C p.K304N | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SYTL5 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- TCHHL1 | c.1892G>A p.G631E | Missense Mutation (SNP) | VAF 115/337 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDG | c.830C>G p.A277G | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- TENM1 | c.2312G>A p.G771E | Missense Mutation (SNP) | VAF 63/359 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- THRA | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- THSD1 | c.2243T>G p.V748G | Missense Mutation (SNP) | VAF 174/463 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TIMM21 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMEM132B | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TMEM132E | c.1624A>G p.M542V (on ENST00000321639; = p.M632V on NM_001304438.2) | Missense Mutation (SNP) | VAF 129/447 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TNC | c.5717C>T p.T1906I | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRIM60 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM69 | c.1223C>T p.T408I (on ENST00000329464 / NM_182985.5; = p.T249I on NM_080745.5) | Missense Mutation (SNP) | VAF 66/417 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TRIP11 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TRIR | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 67/455 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM4 | c.3328C>T p.R1110W | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TRPS1 | c.2575G>T p.G859C (on ENST00000220888 / NM_001330599.2; = p.G872C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/404 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- TSPAN19 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- UMODL1 | c.3610T>G p.S1204A (on ENST00000408910 / NM_001004416.2; = p.S1332A on NM_173568.3) | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP4 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- VCPIP1 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 203/486 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB4 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 62/452 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ZCCHC8 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ZFP14 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ZFR | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 119/393 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF135 | c.1811dup p.P605Afs*3 (on ENST00000313434 / NM_001289401.2; = p.P617Afs*3 on NM_003436.4) | Frame Shift Ins (INS) | VAF 59/484 reads (12%) | called by mutect2, pindel, varscan2
- ZNF268 | c.2395A>T p.M799L | Missense Mutation (SNP) | VAF 58/453 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZNF41 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 53/381 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF469 | c.10753G>A p.G3585R (on ENST00000437464; = p.G3613R on NM_001367624.2) | Missense Mutation (SNP) | VAF 78/424 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZNF469 | c.11269C>T p.Q3757* (on ENST00000437464; = p.Q3785* on NM_001367624.2) | Nonsense Mutation (SNP) | VAF 67/402 reads (17%) | called by muse, mutect2, varscan2
- ZNF484 | c.680A>G p.Q227R | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF626 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2
- ZNF626 | c.257G>A p.W86* | Nonsense Mutation (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- ZNF680 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACTR8 | c.207C>T p.A69= | Silent (SNP) | VAF 45/368 reads (12%) | catalogued as rs937892418; called by muse, mutect2, varscan2
- ADA2 | c.414C>T p.F138= | Silent (SNP) | VAF 48/344 reads (14%) | catalogued as rs770135987, COSV52830462; called by muse, varscan2
- ADA2 | c.378G>A p.R126= | Silent (SNP) | VAF 42/286 reads (15%) | called by muse, varscan2
- ADAMTS6 | c.3318C>T p.F1106= | Silent (SNP) | VAF 50/396 reads (13%) | catalogued as rs747026146; called by muse, mutect2, varscan2
- ADGRL3 | c.2121C>T p.V707= (on ENST00000506720 / NM_001322402.2; = p.V639= on NM_015236.6) | Silent (SNP) | VAF 44/237 reads (19%) | catalogued as rs191345187; called by muse, mutect2, varscan2
- ADH7 | c.87G>A p.E29= | Silent (SNP) | VAF 47/271 reads (17%) | catalogued as rs370564755; called by muse, mutect2, varscan2
- ADORA2A | c.462C>T p.N154= | Silent (SNP) | VAF 59/410 reads (14%) | called by muse, mutect2, varscan2
- ANKRD29 | c.96G>A p.L32= | Silent (SNP) | VAF 132/437 reads (30%) | called by muse, mutect2, varscan2
- ARAP2 | c.5013T>A p.S1671= | Silent (SNP) | VAF 34/303 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.1365G>A p.R455= | Silent (SNP) | VAF 173/455 reads (38%) | catalogued as rs1342121961; called by muse, mutect2, varscan2
- ASTN1 | c.1782C>A p.L594= | Silent (SNP) | VAF 51/260 reads (20%) | called by muse, mutect2, varscan2
- ATP13A5 | c.2118G>A p.K706= | Silent (SNP) | VAF 61/313 reads (19%) | called by muse, mutect2, varscan2
- AZIN2 | c.717C>T p.F239= | Silent (SNP) | VAF 54/304 reads (18%) | called by muse, mutect2, varscan2
- BAIAP2L2 | c.981G>A p.R327= | Silent (SNP) | VAF 60/595 reads (10%) | catalogued as rs1170958970; called by muse, mutect2, varscan2
- C1orf127 | c.2355G>A p.R785= | Silent (SNP) | VAF 63/424 reads (15%) | catalogued as COSV65436747; called by muse, mutect2, varscan2
- C4orf17 | c.1017G>A p.R339= | Silent (SNP) | VAF 33/236 reads (14%) | catalogued as rs776667824, COSV56745386; called by muse, mutect2, varscan2
- CAB39 | c.897G>A p.Q299= | Silent (SNP) | VAF 35/326 reads (11%) | called by muse, mutect2, varscan2
- CACNA1H | c.2751C>T p.T917= | Silent (SNP) | VAF 84/352 reads (24%) | catalogued as rs917812535; called by muse, mutect2, varscan2
- CATSPER3 | c.450C>T p.S150= | Silent (SNP) | VAF 46/350 reads (13%) | catalogued as rs1163587479; called by muse, mutect2, varscan2
- CCNT2 | c.1797G>T p.L599= | Silent (SNP) | VAF 124/373 reads (33%) | catalogued as COSV51474388; called by muse, mutect2, varscan2
- CCP110 | c.405T>A p.T135= | Silent (SNP) | VAF 46/318 reads (14%) | called by muse, mutect2, varscan2
- CDH1 | c.1077A>C p.A359= | Silent (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- CDH9 | c.1059C>T p.H353= | Silent (SNP) | VAF 40/333 reads (12%) | catalogued as rs1196454812, COSV50327964; called by muse, mutect2, varscan2
- CEACAM8 | c.210G>A p.G70= | Silent (SNP) | VAF 76/364 reads (21%) | catalogued as rs757637164, COSV54991032; called by muse, mutect2, varscan2
- CRACR2A | c.1617C>T p.P539= | Silent (SNP) | VAF 41/338 reads (12%) | called by muse, mutect2, varscan2
- CTAGE1 | c.1131G>A p.R377= | Silent (SNP) | VAF 39/291 reads (13%) | called by muse, mutect2, varscan2
- CYP2C8 | c.132G>A p.Q44= | Silent (SNP) | VAF 110/311 reads (35%) | called by muse, mutect2, varscan2
- CYP4F11 | c.858C>T p.F286= | Silent (SNP) | VAF 36/392 reads (9%) | catalogued as COSV56126107; called by muse, mutect2, varscan2
- DENND1C | c.1215C>T p.F405= | Silent (SNP) | VAF 50/338 reads (15%) | catalogued as rs761187263, COSV57568229; called by muse, mutect2, varscan2
- DENND2A | c.2208C>T p.S736= | Silent (SNP) | VAF 47/301 reads (16%) | catalogued as COSV52059995; called by muse, mutect2, varscan2
- DGKK | c.861C>T p.I287= | Silent (SNP) | VAF 46/270 reads (17%) | called by muse, mutect2, varscan2
- DMXL2 | c.795C>T p.C265= | Silent (SNP) | VAF 43/259 reads (17%) | called by muse, mutect2, varscan2
- DNAH17 | c.1518G>A p.T506= | Silent (SNP) | VAF 87/352 reads (25%) | catalogued as rs761793175, COSV101101570, COSV67752131; called by muse, mutect2, varscan2
- DNMT1 | c.3936G>A p.R1312= | Silent (SNP) | VAF 101/425 reads (24%) | called by muse, mutect2, varscan2
- DOK3 | c.657C>T p.S219= | Silent (SNP) | VAF 53/454 reads (12%) | called by muse, mutect2, varscan2
- DZANK1 | c.2145C>T p.D715= (on ENST00000262547 / NM_001099407.1; = p.D522= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/418 reads (24%) | called by muse, mutect2, varscan2
- EHMT2 | c.1707C>T p.S569= | Silent (SNP) | VAF 76/572 reads (13%) | called by muse, mutect2, varscan2
- ELL | c.1758C>T p.T586= | Silent (SNP) | VAF 27/358 reads (8%) | called by muse, mutect2
- ETV3L | c.249G>A p.R83= | Silent (SNP) | VAF 60/340 reads (18%) | catalogued as COSV71901174; called by muse, mutect2, varscan2
- FBL | c.591C>T p.G197= | Silent (SNP) | VAF 45/418 reads (11%) | catalogued as rs1347016852, COSV55683688; called by muse, mutect2, varscan2
- FBN3 | c.5976C>T p.F1992= | Silent (SNP) | VAF 87/342 reads (25%) | called by muse, mutect2, varscan2
- FLG | c.117G>A p.K39= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV64241707, COSV64244634, COSV64245696; called by muse, mutect2, varscan2
- FLRT1 | c.1239G>A p.K413= | Silent (SNP) | VAF 77/728 reads (11%) | called by muse, mutect2, varscan2
- FNIP2 | c.2244C>T p.S748= | Silent (SNP) | VAF 42/373 reads (11%) | called by muse, mutect2, varscan2
- GAL3ST1 | c.588C>T p.F196= | Silent (SNP) | VAF 50/434 reads (12%) | catalogued as COSV58893328; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.555G>A p.E185= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as COSV100374597; called by muse, mutect2, varscan2
- GIMAP8 | c.981C>T p.F327= | Silent (SNP) | VAF 34/252 reads (13%) | called by muse, mutect2, varscan2
- GML | c.453C>T p.I151= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as COSV55277567; called by muse, mutect2
- GRIA1 | c.582G>A p.K194= | Silent (SNP) | VAF 101/375 reads (27%) | catalogued as COSV53624058; called by muse, mutect2, varscan2
- HAVCR2 | c.906G>A p.*302= | Silent (SNP) | VAF 25/202 reads (12%) | called by muse, mutect2, varscan2
- HHIPL1 | c.753C>T p.F251= | Silent (SNP) | VAF 74/366 reads (20%) | called by muse, mutect2, varscan2
- IDUA | c.711C>T p.L237= | Silent (SNP) | VAF 177/618 reads (29%) | catalogued as rs528650871; called by muse, mutect2, varscan2
- IMPG1 | c.9G>A p.L3= | Silent (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- IRX4 | c.1110C>T p.S370= | Silent (SNP) | VAF 50/407 reads (12%) | called by muse, varscan2
- ISX | c.612C>T p.L204= | Silent (SNP) | VAF 105/484 reads (22%) | catalogued as rs376456588; called by muse, varscan2
- ITPR1 | c.4419G>A p.S1473= (on ENST00000354582; = p.S1458= on NM_002222.7) | Silent (SNP) | VAF 94/354 reads (27%) | catalogued as rs770919880; called by muse, mutect2, varscan2
- KCND1 | c.996C>T p.S332= | Silent (SNP) | VAF 75/357 reads (21%) | called by muse, mutect2, varscan2
- KIAA0100 | c.2151C>T p.G717= | Silent (SNP) | VAF 38/414 reads (9%) | called by muse, mutect2
- KIF26B | c.4899C>T p.F1633= | Silent (SNP) | VAF 92/589 reads (16%) | catalogued as COSV63638436; called by muse, mutect2, varscan2
- KIF3B | c.1005C>T p.N335= | Silent (SNP) | VAF 55/428 reads (13%) | catalogued as rs746438023; called by muse, mutect2, varscan2
- KIF5A | c.1245G>A p.Q415= | Silent (SNP) | VAF 120/398 reads (30%) | catalogued as COSV99673563; called by muse, mutect2, varscan2
- KIR2DL3 | c.606C>T p.F202= | Silent (SNP) | VAF 42/352 reads (12%) | called by muse, mutect2
- KIRREL2 | c.2073C>T p.F691= | Silent (SNP) | VAF 134/537 reads (25%) | called by muse, mutect2, varscan2
- KLHL4 | c.741G>A p.L247= | Silent (SNP) | VAF 33/200 reads (17%) | called by muse, mutect2, varscan2
- KMT2A | c.11784C>T p.I3928= | Silent (SNP) | VAF 48/254 reads (19%) | called by muse, varscan2
- KRTAP4-6 | c.444C>T p.S148= | Silent (SNP) | VAF 93/931 reads (10%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1053C>T p.I351= | Silent (SNP) | VAF 49/383 reads (13%) | catalogued as rs369477616; called by muse, mutect2, varscan2
- LINGO4 | c.609C>T p.L203= | Silent (SNP) | VAF 67/330 reads (20%) | called by muse, mutect2, varscan2
- LMLN | c.522C>T p.P174= | Silent (SNP) | VAF 25/203 reads (12%) | catalogued as rs373096446; called by muse, mutect2, varscan2
- LRIT1 | c.1026C>T p.S342= | Silent (SNP) | VAF 56/345 reads (16%) | called by muse, mutect2, varscan2
- LRRK1 | c.1032C>T p.L344= | Silent (SNP) | VAF 35/324 reads (11%) | catalogued as COSV52610312, COSV52613206; called by muse, mutect2, varscan2
- LUC7L3 | c.681A>T p.V227= | Silent (SNP) | VAF 61/237 reads (26%) | called by muse, mutect2, varscan2
- LZTR1 | c.285C>T p.L95= | Silent (SNP) | VAF 88/315 reads (28%) | catalogued as rs932030455, COSV99301457; called by muse, mutect2, varscan2
- MAGED2 | c.304C>T p.L102= | Silent (SNP) | VAF 81/361 reads (22%) | catalogued as COSV99514581; called by muse, mutect2, varscan2
- MCM3AP | c.5187C>T p.V1729= | Silent (SNP) | VAF 77/387 reads (20%) | called by muse, mutect2, varscan2
- ME3 | c.672C>T p.L224= | Silent (SNP) | VAF 36/259 reads (14%) | called by muse, mutect2, varscan2
- MED28 | c.234T>C p.D78= | Silent (SNP) | VAF 52/201 reads (26%) | called by muse, mutect2, varscan2
- MSN | c.226C>T p.L76= | Silent (SNP) | VAF 66/307 reads (21%) | called by muse, mutect2, varscan2
- MSN | c.1659A>G p.R553= | Silent (SNP) | VAF 83/415 reads (20%) | called by muse, mutect2, varscan2
- MTMR1 | c.1212G>A p.V404= | Silent (SNP) | VAF 68/347 reads (20%) | catalogued as COSV64892403; called by muse, mutect2, varscan2
- MUC16 | c.9738C>A p.T3246= | Silent (SNP) | VAF 54/379 reads (14%) | called by muse, mutect2, varscan2
- MUC5B | c.6573G>A p.P2191= | Silent (SNP) | VAF 96/621 reads (15%) | catalogued as rs200460096; called by muse, mutect2, varscan2
- MYO15B | c.6633C>T p.S2211= | Silent (SNP) | VAF 83/294 reads (28%) | catalogued as COSV73824794; called by muse, mutect2, varscan2
- MYO7B | c.3480G>A p.A1160= | Silent (SNP) | VAF 52/395 reads (13%) | catalogued as rs982058278; called by muse, mutect2
- NGFR | c.1080G>A p.R360= | Silent (SNP) | VAF 128/536 reads (24%) | called by muse, mutect2, varscan2
- NKG7 | c.474C>T p.P158= | Silent (SNP) | VAF 33/311 reads (11%) | catalogued as COSV99389895; called by muse, mutect2, varscan2
- NLRP14 | c.2364G>A p.L788= | Silent (SNP) | VAF 63/368 reads (17%) | catalogued as COSV55066955, COSV55068931; called by muse, mutect2, varscan2
- NLRP9 | c.670C>T p.L224= | Silent (SNP) | VAF 55/431 reads (13%) | catalogued as COSV100243240; called by muse, mutect2, varscan2
- NPAS4 | c.2259C>T p.F753= | Silent (SNP) | VAF 52/368 reads (14%) | catalogued as rs1029416212; called by muse, mutect2, varscan2
- NPY4R | c.783G>A p.K261= | Silent (SNP) | VAF 48/279 reads (17%) | called by muse, mutect2, varscan2
- NRK | c.483C>T p.I161= | Silent (SNP) | VAF 28/185 reads (15%) | catalogued as COSV54598842; called by muse, mutect2, varscan2
- NUP155 | c.1578T>C p.S526= (on ENST00000231498 / NM_153485.3; = p.S467= on NM_004298.4) | Silent (SNP) | VAF 38/270 reads (14%) | called by muse, mutect2, varscan2
- ODF3L1 | c.387G>A p.K129= | Silent (SNP) | VAF 39/312 reads (13%) | catalogued as COSV59819934; called by muse, mutect2, varscan2
- OOSP4B | c.55T>C p.L19= | Silent (SNP) | VAF 45/295 reads (15%) | called by muse, mutect2, varscan2
- OPCML | c.27G>T p.L9= | Silent (SNP) | VAF 31/225 reads (14%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.681G>A p.Q227= | Silent (SNP) | VAF 44/264 reads (17%) | catalogued as rs1176745453; called by muse, mutect2, varscan2
- OR2B3 | c.153G>A p.L51= | Silent (SNP) | VAF 245/598 reads (41%) | called by muse, mutect2, varscan2
- OR2C3 | c.744G>A p.V248= | Silent (SNP) | VAF 206/400 reads (52%) | called by muse, mutect2, varscan2
- OR2L13 | c.198C>T p.S66= | Silent (SNP) | VAF 36/242 reads (15%) | catalogued as COSV63550319; called by muse, varscan2
- OR2L13 | c.252C>T p.F84= | Silent (SNP) | VAF 120/270 reads (44%) | called by muse, varscan2
- OR51F2 | c.909G>A p.K303= | Silent (SNP) | VAF 70/236 reads (30%) | catalogued as COSV100438206; called by muse, varscan2
- OTULINL | c.600G>A p.R200= | Silent (SNP) | VAF 73/289 reads (25%) | catalogued as rs764451933, COSV99947397; called by muse, mutect2, varscan2
- PCDHA12 | c.2226C>T p.S742= | Silent (SNP) | VAF 135/463 reads (29%) | called by muse, mutect2, varscan2
- PCDHB10 | c.534C>T p.F178= | Silent (SNP) | VAF 111/447 reads (25%) | catalogued as COSV53381355; called by muse, mutect2, varscan2
- PCDHGA10 | c.1032A>G p.V344= | Silent (SNP) | VAF 39/372 reads (10%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.2274C>T p.S758= | Silent (SNP) | VAF 66/564 reads (12%) | called by muse, mutect2, varscan2
- PDGFRB | c.2565G>A p.S855= | Silent (SNP) | VAF 26/404 reads (6%) | catalogued as rs201473517, COSV55803782; called by muse, mutect2
- PDIA3 | c.936T>G p.S312= | Silent (SNP) | VAF 42/305 reads (14%) | called by muse, mutect2, varscan2
- PGGHG | c.1464C>T p.F488= | Silent (SNP) | VAF 44/302 reads (15%) | catalogued as rs1214530413, COSV66888364; called by muse, varscan2
- PHF8 | c.1842G>A p.T614= (on ENST00000357988 / NM_001184896.1; = p.T578= on NM_015107.3) | Silent (SNP) | VAF 45/197 reads (23%) | catalogued as rs369182537, COSV57683918; called by muse, mutect2, varscan2
- PKD1L1 | c.1284G>A p.V428= | Silent (SNP) | VAF 69/438 reads (16%) | catalogued as rs565751968; called by muse, mutect2, varscan2
- PLD2 | c.1695C>T p.F565= | Silent (SNP) | VAF 34/287 reads (12%) | called by muse, mutect2, varscan2
- PLVAP | c.348C>T p.F116= | Silent (SNP) | VAF 32/285 reads (11%) | catalogued as COSV53087586; called by muse, mutect2, varscan2
- PPRC1 | c.3432C>T p.S1144= | Silent (SNP) | VAF 96/272 reads (35%) | catalogued as rs371094314; called by muse, mutect2, varscan2
- PSG5 | c.24C>T p.P8= | Silent (SNP) | VAF 41/519 reads (8%) | catalogued as rs749335968; called by muse, mutect2
- PTCHD4 | c.876C>T p.S292= | Silent (SNP) | VAF 102/310 reads (33%) | catalogued as COSV59782209; called by muse, mutect2, varscan2
- RABGAP1 | c.1098T>C p.D366= | Silent (SNP) | VAF 26/177 reads (15%) | called by muse, mutect2, varscan2
- RALYL | c.867G>A p.Q289= | Silent (SNP) | VAF 51/306 reads (17%) | called by muse, mutect2, varscan2
- RELL2 | c.336C>T p.S112= | Silent (SNP) | VAF 37/362 reads (10%) | called by muse, mutect2, varscan2
- RIMKLA | c.540C>T p.I180= | Silent (SNP) | VAF 85/332 reads (26%) | called by muse, mutect2, varscan2
- RP1 | c.1512T>C p.S504= | Silent (SNP) | VAF 51/380 reads (13%) | called by muse, mutect2, varscan2
- RPTOR | c.1626C>T p.I542= | Silent (SNP) | VAF 92/444 reads (21%) | catalogued as rs750153454, COSV60815737; called by muse, mutect2, varscan2
- SBK2 | c.441C>T p.A147= | Silent (SNP) | VAF 83/293 reads (28%) | catalogued as COSV60013509; called by muse, mutect2, varscan2
- SCNN1B | c.1866C>T p.S622= | Silent (SNP) | VAF 54/385 reads (14%) | called by muse, mutect2, varscan2
- SEC23B | c.2092C>T p.L698= | Silent (SNP) | VAF 38/339 reads (11%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.1353T>C p.L451= | Silent (SNP) | VAF 49/276 reads (18%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.423C>T p.L141= | Silent (SNP) | VAF 151/642 reads (24%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.4806C>T p.T1602= | Silent (SNP) | VAF 124/486 reads (26%) | catalogued as rs1311090665; called by muse, mutect2, varscan2
- SLC14A2 | c.2499C>T p.L833= | Silent (SNP) | VAF 45/272 reads (17%) | catalogued as rs760645218; called by muse, mutect2, varscan2
- SLC15A2 | c.51C>T p.V17= | Silent (SNP) | VAF 49/410 reads (12%) | catalogued as rs775559415; called by muse, mutect2, varscan2
- SLC22A24 | c.87C>T p.I29= | Silent (SNP) | VAF 48/450 reads (11%) | catalogued as rs1276871366, COSV100400022; called by muse, mutect2, varscan2
- SLC26A3 | c.1038C>T p.I346= | Silent (SNP) | VAF 109/385 reads (28%) | catalogued as rs373747349, COSV60640458; called by muse, mutect2, varscan2
- SLC26A5 | c.273G>T p.G91= | Silent (SNP) | VAF 90/300 reads (30%) | catalogued as COSV100098424; called by muse, mutect2, varscan2
- SLC9A2 | c.1368G>A p.R456= | Silent (SNP) | VAF 50/407 reads (12%) | catalogued as COSV99296139; called by muse, mutect2, varscan2
- SLFN12L | c.279C>T p.F93= (on ENST00000260908 / NM_001363830.1; = p.F111= on NM_001195790.1) | Silent (SNP) | VAF 44/328 reads (13%) | catalogued as COSV53474187; called by muse, mutect2, varscan2
- SORCS2 | c.498G>A p.T166= | Silent (SNP) | VAF 41/303 reads (14%) | catalogued as rs1220629379, COSV61168800; called by muse, mutect2, varscan2
- SPATA16 | c.543G>A p.K181= | Silent (SNP) | VAF 95/364 reads (26%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1434G>A p.E478= | Silent (SNP) | VAF 100/933 reads (11%) | called by muse, mutect2, varscan2
- SPEM3 | c.1464G>A p.L488= | Silent (SNP) | VAF 44/295 reads (15%) | called by muse, mutect2, varscan2
- SPHK2 | c.981C>T p.S327= | Silent (SNP) | VAF 151/513 reads (29%) | catalogued as rs1318730768; called by muse, mutect2, varscan2
- SRCIN1 | c.3141C>T p.F1047= (on ENST00000621492; = p.F1013= on NM_025248.3) | Silent (SNP) | VAF 118/365 reads (32%) | catalogued as rs757863993; called by muse, mutect2, varscan2
- SYNE1 | c.19656C>T p.V6552= (on ENST00000367255 / NM_182961.4; = p.V6481= on NM_033071.3) | Silent (SNP) | VAF 64/180 reads (36%) | catalogued as rs773211579; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TAF11L12 | c.297C>T p.A99= | Silent (SNP) | VAF 40/392 reads (10%) | catalogued as rs1207327480; called by muse, mutect2
- TAF1L | c.4176C>T p.S1392= | Silent (SNP) | VAF 112/343 reads (33%) | catalogued as rs1460241724, COSV99645174; called by muse, mutect2, varscan2
- TBC1D12 | c.996G>A p.K332= | Silent (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- TFAP2B | c.1113G>A p.L371= | Silent (SNP) | VAF 42/350 reads (12%) | catalogued as rs776479837; called by muse, mutect2, varscan2
- TMEM132B | c.2728C>T p.L910= | Silent (SNP) | VAF 111/391 reads (28%) | called by muse, mutect2, varscan2
- TMEM44 | c.909G>A p.A303= (on ENST00000392432 / NM_001166305.2; = p.A256= on NM_138399.5) | Silent (SNP) | VAF 37/345 reads (11%) | catalogued as rs758596508; called by muse, mutect2, varscan2
- TMPRSS7 | c.1929T>G p.S643= (on ENST00000452346; = p.S517= on NM_001042575.2) | Silent (SNP) | VAF 86/346 reads (25%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.1737G>A p.V579= | Silent (SNP) | VAF 70/256 reads (27%) | called by muse, mutect2, varscan2
- TOX2 | c.337C>T p.L113= (on ENST00000358131 / NM_001098798.2; = p.L62= on NM_032883.3) | Silent (SNP) | VAF 116/464 reads (25%) | called by muse, mutect2, varscan2
- TRIM29 | c.1176C>T p.P392= | Silent (SNP) | VAF 54/293 reads (18%) | called by muse, mutect2, varscan2
- TUBE1 | c.579C>T p.I193= | Silent (SNP) | VAF 137/291 reads (47%) | called by muse, mutect2, varscan2
- TXNRD3 | c.564T>A p.V188= | Silent (SNP) | VAF 48/546 reads (9%) | called by muse, mutect2
- UBR5 | c.3612A>T p.S1204= | Silent (SNP) | VAF 28/269 reads (10%) | called by muse, mutect2, varscan2
- UGGT2 | c.2040C>T p.P680= | Silent (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2
- USP15 | c.1008T>G p.G336= (on ENST00000280377 / NM_001351159.2; = p.G307= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 108/428 reads (25%) | called by muse, mutect2, varscan2
- UTRN | c.3612G>A p.T1204= | Silent (SNP) | VAF 40/248 reads (16%) | catalogued as rs780713001; called by muse, mutect2, varscan2
- VCAN | c.597C>T p.G199= | Silent (SNP) | VAF 85/319 reads (27%) | catalogued as COSV54112009; called by muse, mutect2, varscan2
- XPO6 | c.807C>T p.S269= | Silent (SNP) | VAF 51/380 reads (13%) | called by muse, mutect2, varscan2
- ZAP70 | c.249C>T p.L83= | Silent (SNP) | VAF 65/497 reads (13%) | catalogued as COSV53857528; called by muse, mutect2, varscan2
- ZFHX2 | c.1221C>T p.G407= | Silent (SNP) | VAF 98/312 reads (31%) | called by muse, mutect2, varscan2
- ZNF107 | c.1563G>A p.E521= | Silent (SNP) | VAF 43/327 reads (13%) | catalogued as COSV61327068; called by muse, mutect2, varscan2
- ZNF17 | c.246G>A p.K82= | Silent (SNP) | VAF 53/259 reads (20%) | called by muse, mutect2, varscan2
- ZNF267 | c.432T>G p.V144= | Silent (SNP) | VAF 50/285 reads (18%) | called by muse, mutect2, varscan2
- ZNF280A | c.981C>T p.N327= | Silent (SNP) | VAF 70/465 reads (15%) | catalogued as rs375266151; called by muse, mutect2, varscan2
- ZNF468 | c.138C>T p.S46= | Silent (SNP) | VAF 35/248 reads (14%) | catalogued as COSV54696993; called by muse, mutect2, varscan2
- ZNF573 | c.375G>A p.Q125= (on ENST00000536220 / NM_001172692.1; = p.Q67= on NM_152360.3) | Silent (SNP) | VAF 35/245 reads (14%) | called by muse, mutect2, varscan2
- ZNF608 | c.1053T>G p.G351= | Silent (SNP) | VAF 57/389 reads (15%) | called by muse, mutect2, varscan2
- ZNF682 | c.1416G>A p.K472= | Silent (SNP) | VAF 51/370 reads (14%) | called by muse, mutect2, varscan2
- ZNF91 | c.3492A>T p.L1164= | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- ZSCAN5B | c.1428C>T p.F476= | Silent (SNP) | VAF 87/417 reads (21%) | catalogued as rs752006186; called by muse, mutect2, varscan2
- ANK3 | c.12596-466C>T | Intron (SNP) | VAF 92/312 reads (29%) | catalogued as COSV55050860; called by muse, mutect2, varscan2
- COL6A3 | c.4285+41C>T | Intron (SNP) | VAF 28/171 reads (16%) | called by muse, mutect2, varscan2
- HTR3E | c.68-15C>T | Intron (SNP) | VAF 72/424 reads (17%) | catalogued as rs202036764, COSV100093624, COSV58949485; called by muse, mutect2, varscan2
- LAMA3 | c.4998+1527G>A | Intron (SNP) | VAF 37/274 reads (14%) | catalogued as rs768557496; called by muse, varscan2
- LCE1A | c.*71C>T | 3'UTR (SNP) | VAF 47/240 reads (20%) | called by muse, mutect2, varscan2
- PLCXD2 | c.866+6621T>G | Intron (SNP) | VAF 54/370 reads (15%) | called by muse, mutect2, varscan2
- PSTK | c.*109T>G | 3'UTR (SNP) | VAF 63/313 reads (20%) | called by muse, mutect2, varscan2
- SLC39A14 | c.457+1500C>T | Intron (SNP) | VAF 110/312 reads (35%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23975G>A | Intron (SNP) | VAF 74/271 reads (27%) | catalogued as rs867794966, COSV67444095; called by muse, mutect2, varscan2
- SORL1 | c.3461-400C>T | Intron (SNP) | VAF 44/212 reads (21%) | called by muse, mutect2, varscan2
- SWI5 | c.-115G>A | 5'UTR (SNP) | VAF 174/488 reads (36%) | catalogued as rs760926220; called by muse, mutect2, varscan2
- TUBB8 | c.167-26C>T | Intron (SNP) | VAF 140/423 reads (33%) | catalogued as rs551052619; called by muse, mutect2, varscan2
- ZNF528 | c.272-868C>T | Intron (SNP) | VAF 43/325 reads (13%) | catalogued as rs944178580; called by muse, mutect2, varscan2
- ZSCAN2 | c.*602C>T | 3'UTR (SNP) | VAF 44/368 reads (12%) | called by muse, mutect2, varscan2
- ZWILCH | c.*165C>T | 3'UTR (SNP) | VAF 29/172 reads (17%) | catalogued as rs1452464768; called by muse, mutect2, varscan2
